Somatic mutation profile of tumor specimen TARGET-10-PARKEU-09A (aliquot TARGET-10-PARKEU-09A-01D) from TARGET case TARGET-10-PARKEU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,065 days).
Specimen TARGET-10-PARKEU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d119b35a-0e72-4967-b931-d3af4d724135.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARKEU-14A (Bone Marrow Normal), aliquot TARGET-10-PARKEU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8023fbc4-2bd1-461d-b4dc-7604567ff935

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, Frame Shift Del 1, RNA 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 8/101 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 10/95 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C10orf71 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554031001, COSV60507319; called by muse, mutect2, varscan2
- CCDC65 | c.123G>C p.Q41H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs769976507; called by muse, mutect2, varscan2
- CEP170B | c.3529C>T p.R1177W (on ENST00000453495; = p.R1106W on NM_015005.3) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752160900; called by muse, mutect2, varscan2
- GLP2R | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.086); catalogued as rs752406323, COSV104389419; called by muse, mutect2, varscan2
- GSK3A | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs752845859, COSV99725035; called by muse, mutect2, varscan2
- MAGEB10 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV63312555, COSV63312770; called by muse, mutect2, varscan2
- MMP13 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV52823078; called by muse, mutect2
- SALL3 | c.2451C>A p.D817E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV101609969; called by muse, mutect2, varscan2
- TLN2 | c.2326G>A p.V776M | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.551); catalogued as rs139110889; called by muse, mutect2, varscan2
- TMPRSS7 | c.2255C>T p.A752V (on ENST00000452346; = p.A626V on NM_001042575.2) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759865349, COSV69980647; called by muse, mutect2, varscan2
- DSCAM | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GON4L | c.5500del p.V1834Sfs*30 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- MCF2 | c.1097T>G p.I366S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- METTL17 | c.1062T>A p.H354Q | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RSPO3 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- TRIM36 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2O | c.2228C>T p.T743M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- YTHDC1 | c.633A>T p.E211D | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2
- RD3L | c.516C>T p.Y172= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as rs568438434; called by muse, mutect2, varscan2
- TBX20 | c.1332G>A p.T444= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as rs1194051605; called by muse, mutect2, varscan2
- TTN | c.24720T>A p.P8240= (on ENST00000591111; = p.P7313= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/124 reads (39%) | called by muse, mutect2, varscan2
- LRRC75B | c.306+723C>A | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- OFCC1 | n.2354G>C | RNA (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
